Somatic mutation profile of tumor specimen BA2557D (aliquot aq-BA2557D) from BEATAML1.0 case 2352, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.1 years (22,664 days).
Specimen BA2557D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6455b5d-d432-4a52-828b-e45b8fc3e4a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3017D (Solid Tissue Normal), aliquot aq-BA3017D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80d9ff53-721a-43e5-a8ca-815241b99d46

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 3, Silent 2, Nonsense Mutation 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 66/245 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754160659, COSV54102342; called by muse, mutect2, varscan2
- COL1A1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750756697; called by muse, mutect2, varscan2
- DMRTA1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV57925502; called by muse, mutect2, varscan2
- FEZF1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs1328009890; called by muse, mutect2
- GIPC3 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59258261; called by muse, mutect2
- MUC16 | c.25553C>A p.T8518N | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV67456535, COSV67497663; called by muse, mutect2, varscan2
- PCDHA1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV65372406; called by muse, mutect2, varscan2
- TMEM248 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs760112171; called by muse, mutect2, varscan2
- ZDHHC8 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs144289165; called by muse, mutect2, varscan2
- AKAP13 | c.2909C>A p.A970D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- CASD1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPKAPK3 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.02); called by muse, mutect2
- MRC1 | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 120/323 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SCN1A | c.3158A>T p.D1053V (on ENST00000303395 / NM_001202435.3; = p.D1042V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SLC52A1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLIT1 | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2
- WDR45 | c.1078T>A p.F360I (on ENST00000376372 / NM_001029896.2; = p.F361I on NM_007075.3) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CNTLN | c.199C>A p.R67= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99262184; called by muse, mutect2
- FRMPD1 | c.2319C>T p.D773= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as rs779009213; called by muse, mutect2, varscan2
- CA14 | c.76+39C>T | Intron (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- CCM2 | c.31-10574del | Intron (DEL) | VAF 43/143 reads (30%) | called by mutect2, pindel, varscan2
- MYPN | chr10:68106600 A>G | 5'Flank (SNP) | VAF 73/180 reads (41%) | catalogued as rs752772974; called by muse, mutect2, varscan2
- PKD1L2 | n.1327C>G | RNA (SNP) | VAF 50/161 reads (31%) | catalogued as rs944070581; called by muse, mutect2, varscan2
- SRGAP3 | c.1324-1991G>A | Intron (SNP) | VAF 42/161 reads (26%) | catalogued as rs1266712911; called by muse, mutect2, varscan2
